Surgical pathology report (de-identified scan), TCGA case TCGA-IB-A6UG, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-A6UG-01A (Primary Tumor).

[page 1 of 4]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Time Received

Time Transmitted

Ordering Provider

Relevant Information

Location

Copied To

Report Patient

Demographics (for
verification purposes)

Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

Specimen Description

A. Gallbladder

B. Whipple specimen

Clinical Information

Pancreatic ca.

Infectious patient: No

Immunocompromised: No

History of neoplasm: N/A

Diagnosis

A. Gallbladder, Cholecystectomy:

- Chronic cholecystitis.
- Cystic duct lymph node with areas of hyalinization, negative for malignancy.

B. Head of Pancreas (Whipple's Resection):

- Invasive moderate to poorly differentiated duct adenocarcinoma of the pancreas.
- Carcinoma invades through muscularis propria of duodenum and erodes mucosa of the ampulla of Vater.
- Focal extension to inferior margin and margin in the groove of the superior mesenteric vessels.
- Metastatic carcinoma in 16 of 19 dissected lymph nodes.

Reported by:

Electronically signed by:

Verified:

ICD-O-3
Adenocarcinoma duct NOS
8500/3
Site: Head of pancreas
C25.0
7/22/13

[page 2 of 4]
B: Pancreas (Exocrine), Macroscopic
SPECIMEN:
Head of pancreas
Duodenum
PROCEDURE:
Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy
TUMOR SITE:

Pancreatic head
TUMOR SIZE:
Greatest dimension: 3.0 cm
Additional dimensions: 2.5 x 2.0 cm

B: Pancreas (Exocrine), Microscopic
HISTOLOGIC TYPE:
Ductal adenocarcinoma
HISTOLOGIC GRADE:
G3: Poorly differentiated
MICROSCOPIC TUMOR EXTENSION:
Tumor invades peripancreatic soft tissues
Tumor invades retroperitoneal soft tissue
MARGINS:
Margin(s) involved by invasive carcinoma
Uncinate process (retroperitoneal) margin (nonperitonealized surface of the uncinate process)
TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):
Not known
LYMPH-VASCULAR INVASION:
Present
PERINEURAL INVASION:
Present
PRIMARY TUMOR (pT):
pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery
REGIONAL LYMPH NODES (pN):
pN1: Regional lymph node metastasis
Number examined: 19
Number involved: 16
ADDITIONAL PATHOLOGIC FINDINGS:
Pancreatic intraepithelial neoplasia (highest grade: PanIN II)

Gross Description

Received are specimen containers A to B. All requisitions and specimen containers are labelled with the patient's name, ~~specimen~~ cassettes and are labelled with the

A. Specimen is received fresh and subsequently fixed in formalin. The container is designated "gallbladder". The specimen consists of a collapsed gallbladder with abundant fatty tissue around the gallbladder. The gallbladder measures 7.0 cm in length and up to 2.5 cm in transverse diameter. On opening the gallbladder it contains a small amount of mucoid bile as well as small fragments of calculus material ranging from 0.2 cm up to 0.8 cm. The mucosal surface is green and velvety. The gallbladder wall measures up to 0.2 cm in thickness. A cystic duct lymph node is visible at the proximal resection margin. The proximal resection margin and cystic duct lymph node are submitted in A1. Representative sections from the body and fundus are submitted in A2.

B. Specimen is received fresh and subsequently fixed in formalin. The container is designated "Whipple's specimen". The specimen consists of a pancreatic duodenectomy specimen. The duodenal portion measures 32.0 cm in length with a short segment of distal antrum, 2.0 cm in length. The head of pancreas measures 6.0 cm from superior to inferior, 3.5 cm from medial to lateral and approximately 3.5 cm in thickness from anterior surface to retroperitoneal resection margin. The superior mesenteric vessel

[page 3 of 4]
groove is painted green and the protruding uncinate process is painted orange. The retroperitoneal soft tissue margin is painted black. The resection margin at the neck of the pancreas is painted blue. The ampulla of Vater is somewhat protuberant, measuring 1.5 cm across with mucosal congestion. The gallbladder is layed open to reveal a firm tumorous mass encircling the common bile duct starting 0.8 cm from the opening of the ampulla and extending out the common bile duct for a distance of 2.0 cm. The remaining proximal common bile duct is 2.5 cm from the proximal extent of the mass. There is a bifurcation, likely representing a low insertion of the cystic duct. The bifurcation lies 1.5 cm from the proximal common bile duct margin. An incision from the uncinate process aspect at the head of pancreas shows a hard tumorous mass that occupies approximately 50% of the head of pancreas measuring 3.0 cm from superior to inferior, approximately 2.0 cm from the wall of the common bile duct in a medial-lateral orientation and approximately 2.5 cm in thickness in AP orientation. The tumor appears to lie closest to the retroperitoneal resection margin although soft friable fatty tissue is present at the surface. The section of the soft tissue around the head of the pancreas yields a distinct node at the proximal end of the common bile duct, two lymph nodes along the superior edge of the head of pancreas, approximately four enlarged firm areas, possibly nodes, in the adipose tissue attached to the distal stomach, approximately four lymph nodes in the gastroduodenal zone and approximately three lymph nodes in the fatty tissue at the inferior aspect at the head of pancreas.

Sections are taken as follows:

- B1 - proximal common bile duct resection margin.
- B2 - resection margin at neck of pancreas
- B3 - inferior edge at head of pancreas, perpendicular.
- B4 through B7 - transverse sections of posterior aspect of pancreatic head from inferior to superior.
- B8 through B13 - transverse sections of anterior half of head of pancreas from inferior to superior.
- B14 - lymph node at proximal end of common bile duct.
- B15 - lymph nodes at superior edge of head of pancreas.
- B16 and B17 - lymph nodes on lesser curve of stomach.
- B18 and B19 - gastroduodenal lymph nodes.
- B20 - lymph nodes at inferior edge at head of pancreas.
- B21 - representative section of proximal resection margin, perpendicular.
- B22 - distal resection margin, perpendicular.

Microscopic Description

A. Sections show gallbladder tissue with chronic cholecystitis, but no cytologic atypia in the mucosa of the gallbladder. The cystic duct lymph node shows accumulation of macrophages with areas of hyalinization, but without significant mineral oil lipogranulomatosis. No sign of malignancy is present.

B. Sections of the head of pancreas shows an invasive moderate to poorly differentiated pancreatic duct adenocarcinoma that invades along the distal common bile duct, extends through the wall adjacent duodenum and involves the orifice of the ampulla of Vater. The bulk of the cancer, however, lies in the inferior part of the head of the pancreas focally extending to a cauterized inferior margin and focally to a cauterized edge in the groove of the superior mesenteric vessels. There is also areas of lymphovascular invasion and perineural invasion. Focal residual ducts on the periphery of the cancer shows changes of PANIN grade II. The pancreatic neck resection margin is clear and no

clear involvement of the main pancreatic duct can be seen. Also, the secondary pancreatic papilla is visualized with no direct invasion by cancer. The proximal resection of the common bile duct is clear of tumor. Multiple lymph nodes included in the sections of the head of the pancreas shows metastatic carcinoma and together with additional lymph nodes dissected separately, there appears to be up to 19 lymph nodes, including the nodes in the distal perigastric tissue. Sixteen of these show either

[page 4 of 4]
be metastatic deposits of pancreatic carcinoma.

The sections of the proximal margin show unremarkable distal gastric antral mucosa and unremarkable duodenal mucosa, and the distal resection margin is clear with unremarkable duodenal mucosa.

Accession Number
Encounter Number
Patient Location

HIFAA Discrepancy		☒

Source: NCI Genomic Data Commons file a6338da6-291d-47ea-bbf0-cfd6eabb11b9 (TCGA-IB-A6UG.E1FA7F32-07A8-435B-BA17-133EFD0295D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).